CCDI case PBCHRJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/8a09c5d5-ee4a-47c6-bd3c-b09da55ead6c

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Pleomorphic xanthoastrocytoma: ICD-O-3 morphology code: 9424/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.7 years (6,114 days).

Biospecimens (3 samples)
- Sample 0DS6KT: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DS6L8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DS6LM: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
